Surgical pathology report (de-identified scan), TCGA case TCGA-AH-6549, project TCGA-READ (Rectum Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AH-6549-01A (Primary Tumor).

[page 1 of 2]
QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Vermiform appendix:

No pathological diagnosis.

B. Rectal mass resection:

Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.

2. Histologic grade: Moderately differentiated (low grade).

3. Tumor site: Rectum.

4. Tumor size: 5.5 x 5.0 x 3.5 cm in aggregate.

5. Lymphovascular space invasion: Present.

6. Microscopic tumor extension:

a. Tumor invades completely through muscularis propria into surrounding perirectal soft tissue.

7. Treatment effect: None identified.

Surgical Margin Status:

1. See comment.

Lymph Node Status:

1. Total number of lymph nodes received: None.

Other:

1. Other significant findings: See comment below.

2. pTNM stage: pT3, NX.

COMMENTS:

The vast majority of the sample submitted consists of invasive tumor. It is unclear what represents the exact margins in many of the sampled areas. However, where the margins can be clearly identified, tumor is seen at one focus 0.1 cm from the inked radial margin and appears to be within 0.2 cm of both the proximal and distal mucosal margins. However, since the majority of the specimen does consist of tumor there is judged to be a significant risk that tumor is present at one of the resection margins. Clinical correlation is suggested.

CLINICAL HISTORY:

Preoperative Diagnosis: with a rectal mass

[page 2 of 2]
Postoperative Diagnosis:
Symptoms/Radiologic Findings:
SPECIMENS:
A. Appendix
B. Rectal mass

GROSS DESCRIPTION:

The specimen is received in two containers labeled

A. Additionally labeled appendix and contains a partially fragmented tan gray vermiform appendix that when reconstructed is approximately 6.5 cm in length and ranges from 0.7 up to 1.5 cm in diameter. The serosa is pink tan and shaggy and features a minimal amount of adherent yellow tan mesoappendix. Sectioning reveals a pinpoint lumen with no perforations or fecaliths. Representative sections are submitted in cassette A labeled (proximal margin notched).

B. Additionally labeled rectal mass and contains two tan pink polypoid soft tissues, 5.5 x 4.5 x 3.0 cm and 2.5 x 1.5 x 1.0 cm. A cauterized margin is present on the largest piece. This margin is inked and the pieces are sectioned and entirely submitted in cassettes B1-B19 labeled designated as follows: 1-- smallest piece, sectioned; 2-19-- largest piece to include inked margin in cassettes B2-B15.

A yellow and green cassette are submitted for genomic research each labeled

Source: NCI Genomic Data Commons file 204ce489-b9d3-40be-9442-ead93816ba8d (TCGA-AH-6549.BCCEAD66-F8D2-4618-9B2D-BA3B31B1B1A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).